Somatic mutation profile of tumor specimen 0DAVLW from CCDI case PBBJZI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Craniopharyngioma, adamantinomatous; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.4 years (4,172 days).
Specimen 0DAVLW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b5083873-6a1d-49eb-a8ce-c50680888109.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DAVIY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/83f4ee8c-dada-477f-8ba0-f508c7abd15f

The open-access MAF lists 7 somatic variants for this specimen: 1 protein-altering or splice-affecting, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 3, 5'UTR 2, Missense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYO1G | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 42/543 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.028); catalogued as rs745778626; called by muse, mutect2
- CNTNAP3B | c.-59del | 5'UTR (DEL) | VAF 3/22 reads (14%) | called by mutect2, varscan2
- DPH7 | c.-97G>T | 5'UTR (SNP) | VAF 3/19 reads (16%) | called by mutect2, varscan2
- NCOA7 | c.-64-35T>A | Intron (SNP) | VAF 5/42 reads (12%) | called by muse, varscan2
- SAG | c.648+59C>A | Intron (SNP) | VAF 4/12 reads (33%) | called by muse, varscan2
- STARD13 | c.*96C>G | 3'UTR (SNP) | VAF 5/78 reads (6%) | called by muse, mutect2
- WT1 | c.966-45G>T | Intron (SNP) | VAF 3/22 reads (14%) | catalogued as rs1375924654; called by muse, varscan2
